Somatic mutation profile of tumor specimen C3N-03212-01 (aliquot CPT0185230006) from CPTAC case C3N-03212, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 70.3 years (25,659 days).
Specimen C3N-03212-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bf9f57a-d400-4768-9682-e54d84e2a3f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03212-31 (Blood Derived Normal), aliquot CPT0185290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9b5823a-86b7-480f-b6e5-b6f70d963418

The open-access MAF lists 75 somatic variants for this specimen: 45 protein-altering or splice-affecting, 18 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Intron 6, Nonsense Mutation 3, Splice Region 2, 3'UTR 2, 5'UTR 2, 3'Flank 1, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 106/827 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AP5Z1 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs756182519, COSV62242666; ClinVar: uncertain significance; called by muse, mutect2
- CPD | c.2771C>G p.S924* | Nonsense Mutation (SNP) | VAF 7/182 reads (4%) | catalogued as COSV56716240; called by muse, mutect2
- CRACD | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 37/541 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV51715264; called by muse, mutect2
- HMCN1 | c.8729G>T p.G2910V | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634119; called by muse, mutect2
- KIF5A | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1174310373, COSV54052774; called by muse, mutect2
- MAGEB17 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1446914265, COSV61556834; called by muse, mutect2
- MAGEE1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV63910591; called by muse, mutect2
- MUC16 | c.35783C>A p.S11928* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV67453526; called by muse, mutect2
- MXD3 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 30/385 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1415384768; called by muse, mutect2
- NLRP7 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.281); catalogued as rs878926490, COSV60177949; called by muse, mutect2, varscan2
- OR2L3 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as rs915001765; called by muse, mutect2
- PRUNE2 | c.6145G>T p.V2049L | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs1331678251; called by muse, mutect2
- SCARF2 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1221991531; called by muse, mutect2
- SOX3 | c.197C>G p.T66R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV100983789; called by muse, mutect2
- VBP1 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV53972056; called by muse, mutect2
- WDR13 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1556994825, COSV54334317; called by muse, mutect2, varscan2
- XIRP2 | c.8825G>A p.R2942H (on ENST00000628543; = p.R3117H on NM_152381.6) | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54684198, COSV54687421, COSV54705186; called by muse, mutect2
- ABCC12 | c.3201C>G p.S1067R | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- AKAP9 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ALCAM | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOL2 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); called by muse, mutect2
- BRD8 | c.3623A>G p.N1208S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD33 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2
- CHST7 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.049); called by muse, mutect2
- CLOCK | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLTCL1 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- CPT1B | c.353T>G p.V118G | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.273); called by muse, mutect2
- DIAPH3 | c.2590C>G p.L864V (on ENST00000400324 / NM_001042517.2; = p.L601V on NM_030932.3) | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- DRC3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2
- FBXO31 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- GALNT10 | c.1551G>C p.Q517H | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- GDF7 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIK3 | c.2732G>A p.S911N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- HNRNPUL2 | c.775_780del p.V259_S260del | In Frame Del (DEL) | VAF 18/156 reads (12%) | called by mutect2, pindel
- NSRP1 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PLXNA4 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPT1 | c.124+7G>A | Splice Region (SNP) | VAF 81/669 reads (12%) | called by muse, mutect2, varscan2
- RNF148 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC18A2 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 61/595 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- SLC4A7 | c.3391C>A p.L1131I | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- SMARCA4 | c.4635+8C>A | Splice Region (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- TEX26 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TGM4 | c.129C>A p.H43Q | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- YIF1A | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 54/321 reads (17%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1893C>A p.S631= | Silent (SNP) | VAF 36/591 reads (6%) | catalogued as COSV54455891; called by muse, mutect2
- CEP295NL | c.1437G>A p.T479= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as rs956253363, COSV53161770; called by muse, mutect2, varscan2
- CFAP47 | c.9213C>T p.F3071= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- CRTAP | c.342C>G p.R114= | Silent (SNP) | VAF 58/395 reads (15%) | called by muse, mutect2, varscan2
- DYSF | c.5373G>A p.P1791= | Silent (SNP) | VAF 33/409 reads (8%) | catalogued as rs759536240; ClinVar: likely benign; called by muse, mutect2
- EVX1 | c.1062C>T p.S354= | Silent (SNP) | VAF 61/1094 reads (6%) | catalogued as rs769990490; called by muse, mutect2
- FBXW5 | c.57G>T p.L19= | Silent (SNP) | VAF 40/510 reads (8%) | called by muse, mutect2
- GPR152 | c.207C>G p.L69= | Silent (SNP) | VAF 23/229 reads (10%) | called by muse, mutect2, varscan2
- GSN | c.2262C>A p.P754= | Silent (SNP) | VAF 46/382 reads (12%) | catalogued as COSV100376194; called by muse, mutect2, varscan2
- HPR | c.342C>T p.S114= | Silent (SNP) | VAF 41/511 reads (8%) | called by muse, mutect2
- ITFG1 | c.1227C>T p.I409= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PEAK1 | c.4632C>G p.T1544= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- RAD54L2 | c.3618G>A p.P1206= | Silent (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- SCN5A | c.5436G>T p.S1812= (on ENST00000333535 / NM_198056.3; = p.S1811= on NM_000335.5) | Silent (SNP) | VAF 54/729 reads (7%) | catalogued as COSV61137404; called by muse, mutect2
- TAB2 | c.1065C>T p.V355= | Silent (SNP) | VAF 50/254 reads (20%) | called by muse, mutect2, varscan2
- TACC2 | c.6714G>A p.T2238= (on ENST00000334433; = p.T316= on NM_006997.4) | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- WWC1 | c.1074C>T p.S358= | Silent (SNP) | VAF 77/597 reads (13%) | catalogued as rs746048134; called by muse, mutect2, varscan2
- ZNF579 | c.588G>A p.S196= | Silent (SNP) | VAF 82/355 reads (23%) | catalogued as rs964452982; called by muse, mutect2, varscan2
- AC073316.1 | chr7:3140267 G>A | 3'Flank (SNP) | VAF 8/178 reads (4%) | catalogued as rs899917604; called by muse, mutect2
- ALDH3B1 | c.*196C>T | 3'UTR (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- ATP2B4 | c.3309+2042G>C | Intron (SNP) | VAF 64/442 reads (14%) | called by muse, mutect2, varscan2
- DCDC1 | c.2715+8111C>T | Intron (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- DYNC1H1 | c.12103-14T>G | Intron (SNP) | VAF 60/658 reads (9%) | called by muse, mutect2
- ERN2 | c.306+919C>T | Intron (SNP) | VAF 16/239 reads (7%) | catalogued as rs762522285, COSV56831942; called by muse, mutect2
- FGD4 | c.-18G>A | 5'UTR (SNP) | VAF 44/476 reads (9%) | called by muse, mutect2
- GLYATL1 | n.322C>G | RNA (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- MEIS1 | c.*171G>A | 3'UTR (SNP) | VAF 24/270 reads (9%) | catalogued as rs746473840; called by muse, mutect2
- MGRN1 | c.-50C>T | 5'UTR (SNP) | VAF 22/452 reads (5%) | called by muse, mutect2
- NRK | c.4354-848C>T | Intron (SNP) | VAF 28/202 reads (14%) | called by muse, mutect2, varscan2
- TRPM8 | c.2761+63C>G | Intron (SNP) | VAF 45/190 reads (24%) | called by muse, mutect2, varscan2
